Somatic mutation profile of tumor specimen C3L-09397-01 (aliquot CPT0502540006) from CPTAC case C3L-09397, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 68.8 years (25,120 days).
Specimen C3L-09397-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30757104-8640-4529-810e-033fb95a4e88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09397-31 (Blood Derived Normal), aliquot CPT0502630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b851d97f-c7e4-4889-86e6-389c2cfb1ae7

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.1378-6154G>A | Intron (SNP) | VAF 23/448 reads (5%) | catalogued as rs193922423, CM076074, COSV99949608; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TGFBR2 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918714, COSV55445679, COSV55458087, COSV55461455; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- WNT7A | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893835, CM063228; ClinVar: pathogenic; called by muse, mutect2
- ASIC5 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 45/560 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV101539702; called by muse, mutect2
- CCDC97 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 62/616 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1250007615, COSV54191585; called by muse, mutect2, varscan2
- COL22A1 | c.1793G>C p.R598P | Missense Mutation (SNP) | VAF 30/433 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100277314; called by muse, mutect2
- COL4A1 | c.4648G>T p.V1550L | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs774251351, COSV101011012, COSV65426479; called by muse, mutect2
- CT47B1 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs778145227, COSV64890691; called by muse, mutect2, varscan2
- DNAH5 | c.12595C>T p.R4199C | Missense Mutation (SNP) | VAF 44/605 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374874272; called by muse, mutect2
- DUSP10 | c.913A>G p.S305G | Missense Mutation (SNP) | VAF 34/619 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60459190; called by muse, mutect2
- EPHA2 | c.1901C>T p.T634I | Missense Mutation (SNP) | VAF 50/545 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs371377772; called by muse, mutect2
- ERBIN | c.3278C>G p.S1093C | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as rs747727899, COSV99397717; called by muse, mutect2
- ESR1 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 42/760 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.676); catalogued as rs754125870; called by muse, mutect2
- FAM47B | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs201715948, COSV61453537; called by muse, mutect2, varscan2
- FAM83E | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 68/684 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.399); catalogued as rs751718316; called by muse, mutect2
- FOCAD | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs369416690; called by muse, mutect2
- GALNT1 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52453626; called by muse, mutect2
- GPR156 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs775980033; called by muse, mutect2
- KCNA6 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 52/646 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54974157; called by muse, mutect2
- KCNC3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 56/686 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100979141; called by muse, mutect2
- KPRP | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 47/633 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs776972984, COSV64220986; called by muse, mutect2
- LRP4 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1216367812; called by muse, mutect2
- MYO9B | c.5704G>A p.E1902K | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456847847, COSV68280544; called by muse, mutect2
- MYOM2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 18/525 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs758822676, COSV100037002, COSV50732411; called by muse, mutect2
- NCOA1 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1204504422, COSV56039492; called by muse, mutect2
- OR5L1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100449930, COSV61733253; called by muse, mutect2
- PACC1 | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs749818718; called by muse, mutect2
- PCNT | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs900057602; called by muse, mutect2
- PHC3 | c.2008C>T p.P670S (on ENST00000494943 / NM_001308116.2; = p.P682S on NM_024947.4) | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as rs1470192058; called by muse, mutect2
- SCN11A | c.3574T>G p.F1192V | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100182793; called by muse, mutect2
- TIMM50 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778355943, COSV58678552; called by muse, mutect2
- USH2A | c.2135C>G p.S712* | Nonsense Mutation (SNP) | VAF 34/335 reads (10%) | catalogued as CD058336, COSV56405884; called by muse, mutect2, varscan2
- USP26 | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM056720, COSV63707956; called by muse, mutect2, varscan2
- XPO7 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs1325181875; called by muse, mutect2
- ABCA12 | c.1982A>G p.K661R (on ENST00000272895 / NM_173076.3; = p.K343R on NM_015657.3) | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- ABCG2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACVR1B | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 37/306 reads (12%) | called by pindel, varscan2
- CNTNAP4 | c.2204A>G p.Y735C | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CTNND2 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2
- EYS | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2
- GABRD | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRIK2 | c.2221A>C p.T741P | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2
- GSG1L | c.890A>G p.Y297C (on ENST00000447459 / NM_001109763.2; = p.Y142C on NM_144675.2) | Missense Mutation (SNP) | VAF 27/325 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- HYDIN | c.11063T>A p.V3688D | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.127); called by muse, mutect2
- OR6C70 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2
- PIGR | c.1570dup p.S524Kfs*15 | Frame Shift Ins (INS) | VAF 50/544 reads (9%) | called by mutect2, pindel
- PKDREJ | c.3715G>A p.G1239R | Missense Mutation (SNP) | VAF 42/417 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA3 | c.337_339del p.E113del | In Frame Del (DEL) | VAF 50/288 reads (17%) | called by pindel, varscan2
- PPRC1 | c.4537G>A p.D1513N | Missense Mutation (SNP) | VAF 31/433 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- PTCHD3 | c.1652G>T p.W551L | Missense Mutation (SNP) | VAF 45/625 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- SPATA48 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2
- STAG1 | c.2518G>T p.D840Y | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- STXBP5L | c.2543C>A p.T848N | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.457); called by muse, mutect2
- STXBP5L | c.3179A>C p.N1060T | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); called by muse, mutect2
- TTC14 | c.1919A>G p.K640R | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.219); called by muse, mutect2
- UQCC1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.385); called by muse, mutect2
- WNT5A | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.352); called by muse, mutect2
- ZC2HC1A | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZEB2 | c.2600A>C p.K867T | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARHGAP6 | c.2232C>T p.S744= (on ENST00000337414 / NM_013427.3; = p.S541= on NM_013423.3) | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs759367604, COSV57298073; called by muse, mutect2, varscan2
- ATR | c.5679C>T p.S1893= | Silent (SNP) | VAF 26/464 reads (6%) | called by muse, mutect2
- CHST3 | c.927G>A p.S309= | Silent (SNP) | VAF 56/592 reads (9%) | catalogued as rs1013851768, COSV64151228; called by muse, mutect2
- CPNE8 | c.438C>A p.I146= | Silent (SNP) | VAF 12/250 reads (5%) | catalogued as COSV58842556; called by muse, mutect2
- DHRS7C | c.561G>A p.P187= (on ENST00000330255 / NM_001220493.2; = p.P186= on NM_001105571.3) | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as rs892489854; called by muse, mutect2
- OR8K1 | c.348T>A p.S116= | Silent (SNP) | VAF 27/563 reads (5%) | catalogued as rs746377909; called by muse, mutect2
- PCDHB7 | c.735G>A p.S245= | Silent (SNP) | VAF 40/496 reads (8%) | catalogued as rs781976935, COSV50760322; called by muse, mutect2
- PLEKHG3 | c.1032C>G p.T344= (on ENST00000394691; = p.T400= on NM_001308147.2) | Silent (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- REV3L | c.6984C>T p.I2328= | Silent (SNP) | VAF 39/476 reads (8%) | called by muse, mutect2
- RTL1 | c.1842G>A p.A614= | Silent (SNP) | VAF 46/600 reads (8%) | catalogued as rs776826109; called by muse, mutect2
- SAMD9L | c.348A>G p.S116= | Silent (SNP) | VAF 24/412 reads (6%) | catalogued as COSV100560526; called by muse, mutect2
- SLC22A2 | c.1153C>T p.L385= | Silent (SNP) | VAF 32/452 reads (7%) | catalogued as COSV65267302; called by muse, mutect2
- SULF1 | c.39G>C p.L13= | Silent (SNP) | VAF 26/380 reads (7%) | called by muse, mutect2
- THSD7B | c.3036C>T p.C1012= | Silent (SNP) | VAF 20/601 reads (3%) | called by muse, mutect2
- TPP1 | c.1056C>T p.L352= | Silent (SNP) | VAF 37/420 reads (9%) | catalogued as COSV54993454; called by muse, mutect2
- UNC45A | c.1371C>T p.A457= | Silent (SNP) | VAF 46/600 reads (8%) | catalogued as rs200598683; called by muse, mutect2
- MIR550A3 | chr7:29684849 C>T | 5'Flank (SNP) | VAF 62/668 reads (9%) | catalogued as rs1382524463; called by muse, mutect2
